Somatic mutation profile of tumor specimen TCGA-FE-A234-01A (aliquot TCGA-FE-A234-01A-11D-A14W-08) from TCGA case TCGA-FE-A234, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 26.6 years (9,724 days).
Specimen TCGA-FE-A234-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2b03ecd-9e42-41d0-8a14-949263ed66c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FE-A234-10A (Blood Derived Normal), aliquot TCGA-FE-A234-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/125ec66b-b8e3-40f9-8e76-82acadb3845d

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- MBTPS1 | c.2911C>A p.Q971K | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated, low confidence (0.44); PolyPhen possibly damaging (0.761); catalogued as COSV58570673; called by muse, mutect2, varscan2
- RAPGEF1 | c.3032A>G p.K1011R | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV64699503; called by muse, mutect2, varscan2
- MACF1 | c.15832-10647A>T | Intron (SNP) | VAF 23/93 reads (25%) | catalogued as COSV57120652; called by muse, mutect2, varscan2
- USP32 | c.1239+4591G>T | Intron (SNP) | VAF 21/59 reads (36%) | catalogued as COSV100342037; called by muse, mutect2, varscan2
